Somatic mutation profile of tumor specimen TARGET-20-PASZBM-09A (aliquot TARGET-20-PASZBM-09A-01D) from TARGET case TARGET-20-PASZBM, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.6 years (4,600 days).
Specimen TARGET-20-PASZBM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f54b0b0-bf2f-459b-874b-d27bba6b232c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASZBM-14A (Bone Marrow Normal), aliquot TARGET-20-PASZBM-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbadccfa-1b6e-480e-94d4-56b5bbf0db36

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 17/216 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- GATA2 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV62003359; called by muse, mutect2, varscan2
- CEBPA | c.64_74del p.P22Afs*82 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- EP300 | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 36/91 reads (40%) | called by muse, mutect2, varscan2
